Gene-level copy-number profile of tumor specimen TCGA-63-A5MW-01A from TCGA case TCGA-63-A5MW, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5MW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.996809ca-175c-4009-9e74-51e4a37f9fbb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2dcb43b4-a4c6-4d31-b43b-0007b9930d59

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 1,563; copy number 2: 17,000; copy number 3: 21,006; copy number 4: 10,685; copy number 5: 3,910; copy number 6: 2,288; copy number 7: 795; copy number 8: 1,142; copy number 9: 136; copy number 10: 48; copy number 11: 495; copy number 14: 341; copy number 15: 369; copy number 17: 24; copy number 19: 1; copy number 36: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MW-01A-11D-A26L-01): tumor purity 0.66, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,208,082–141,208,376, 1 gene: RPS16P3.
- chr13:97,901,653–98,024,296, 4 genes (within-gene range 0–2): RPL7AP61, AL356580.1, IPO5, FTLP8.
- chr17:72,425,939–72,428,852, 1 gene: AC007639.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,353 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,234,861–192,917,856, 319 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 14–15 (broad region; genes not listed).
- chr6:50,042,099–60,942,327, 138 genes, copy number 7–10 (broad region; genes not listed).
- chr7:85,636,013–116,508,541, 560 genes, copy number 9–36 (within-gene range 2–36) (broad region; genes not listed).
- chr8:94,352,923–145,066,685, 819 genes, copy number 7–8 (broad region; genes not listed).
- chr11:15,966,449–16,739,591, 1 gene, copy number 7 (within-gene range 6–7): SOX6.
- chr11:16,484,084–20,509,338, 107 genes, copy number 7 (broad region; genes not listed).
- chr11:30,830,369–35,421,002, 87 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).
- chr11:39,161,453–43,856,617, 42 genes, copy number 8–9 (within-gene range 5–9): AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1, LRRC4C, Y_RNA, AC090720.1, RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740, AC109810.1, AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6, AC068205.1, MIR670, MIR670HG, AC068205.2, MIR129-2, HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4.
- chr11:45,355,371–49,379,669, 140 genes, copy number 8 (broad region; genes not listed).
- chr11:56,345,945–60,687,267, 206 genes, copy number 8 (broad region; genes not listed).
- chr11:68,980,021–71,252,577, 57 genes, copy number 8 (within-gene range 5–8): MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:81,552,226–85,656,547, 54 genes, copy number 7: MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A.
- chr11:86,431,590–90,226,538, 109 genes, copy number 7–11 (broad region; genes not listed).
- chr11:90,282,560–90,555,857, 2 genes, copy number 7: TUBAP2, MIR4490.
- chr22:46,481,329–46,548,196, 2 genes, copy number 7: AL031597.1, AL021392.1.

Autosomal genes at a single copy (total copy number 1): 448. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
